CCDI case PBBWFG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ea05ca98-34d3-4b57-8ea2-24a40dbe42e0

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.7 years (2,830 days).

Biospecimens (3 samples)
- Sample 0DIW6A: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIW76: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIW7U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
